Somatic mutation profile of tumor specimen ALCH-B4C8-TTP1-A (aliquot ALCH-B4C8-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B4C8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.2 years (25,291 days).
Specimen ALCH-B4C8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bf6caf8-74c4-4ae1-b5f5-0feac0a533b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4C8-NB1-A (Blood Derived Normal), aliquot ALCH-B4C8-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2edc6cc-ccab-4863-8c4d-bd6f7c010551

The open-access MAF lists 1,467 somatic variants for this specimen: 996 protein-altering or splice-affecting, 298 silent, 173 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 869, Silent 298, Intron 76, Nonsense Mutation 58, RNA 29, 5'UTR 23, 3'UTR 23, Frame Shift Del 22, Splice Site 19, Splice Region 16, 5'Flank 15, Frame Shift Ins 7.

Variants (750 of 1,467; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 42/94 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519921, COSV67960034, COSV67960332, COSV67961305; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SUMF1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs387906976, CM051673; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 71/178 reads (40%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABHD8 | c.1182C>G p.D394E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56046031; called by muse, mutect2, varscan2
- ACTC1 | c.570C>A p.Y190* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as COSV99291957; called by muse, mutect2, varscan2
- ADAM2 | c.571T>C p.Y191H | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1035802784; called by muse, mutect2, varscan2
- ADAM21 | c.1214T>C p.M405T | Missense Mutation (SNP) | VAF 126/448 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1225114049; called by muse, mutect2, varscan2
- ADAMTS15 | c.2728G>T p.G910C | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100143578; called by muse, mutect2, varscan2
- ADAMTS20 | c.1487G>C p.G496A | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316681814, COSV101240757; called by muse, mutect2, varscan2
- ADCK5 | c.1396G>T p.V466F | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as COSV104395016; called by muse, mutect2, varscan2
- ADCY1 | c.2259G>C p.M753I | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52029900; called by muse, mutect2, varscan2
- ADGRD1 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1319401009; called by muse, mutect2, varscan2
- ADGRD1 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs753279251, COSV55443926; called by muse, mutect2, varscan2
- ADGRG7 | c.963C>G p.C321W | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV56303073, COSV99841044; called by muse, mutect2, varscan2
- AHNAK2 | c.7349A>C p.E2450A | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1433063454; called by muse, mutect2, varscan2
- ALG1 | c.1150G>T p.G384W | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM166636, COSV52158394; called by muse, mutect2, varscan2
- ALOX15 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as CM138039, COSV53396108; called by muse, mutect2
- ANKRD11 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs1298734986, COSV56365526; called by muse, mutect2, varscan2
- ANKRD30B | c.1734G>A p.E578= | Splice Region (SNP) | VAF 36/91 reads (40%) | catalogued as rs1461975617; called by muse, mutect2, varscan2
- ANKRD33 | c.98C>A p.A33D (on ENST00000340970 / NM_001304459.2; = p.A168D on NM_182608.4) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771047912; called by muse, mutect2, varscan2
- AOX1 | c.2993C>A p.A998E | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs192036221; called by muse, mutect2, varscan2
- APOB | c.12460G>A p.E4154K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as rs767587977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.5099A>G p.D1700G | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs764352808; called by muse, mutect2, varscan2
- ARHGDIB | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56762315; called by muse, mutect2, varscan2
- ARHGEF11 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as rs745957344, COSV63812599; called by muse, mutect2, varscan2
- ARID1A | c.1939G>C p.D647H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61373425; called by muse, mutect2, varscan2
- ATP11A | c.3032T>A p.V1011E | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV52123346; called by muse, mutect2, varscan2
- ATR | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV63392189; called by muse, mutect2
- ATXN1L | c.353A>C p.Q118P | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs970787188; called by muse, mutect2, varscan2
- ATXN7L1 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs572400300, COSV66300278; called by muse, mutect2
- AZU1 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52140167; called by muse, mutect2, varscan2
- BBS1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs761601575, COSV59149420; called by muse, varscan2
- BCKDHB | c.951+1G>T p.X317_splice | Splice Site (SNP) | VAF 46/182 reads (25%) | catalogued as CS126903; called by muse, mutect2, varscan2
- BCL9 | c.2363C>G p.S788C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as rs1283081622; called by muse, mutect2, varscan2
- C1orf87 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.13); catalogued as COSV64597196; called by muse, mutect2, varscan2
- C2orf16 | c.4927C>T p.Q1643* | Nonsense Mutation (SNP) | VAF 48/332 reads (14%) | catalogued as COSV62675679; called by muse, mutect2, varscan2
- C6 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 40/273 reads (15%) | catalogued as COSV54714318; called by muse, mutect2, varscan2
- C7 | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as CM994345; called by muse, mutect2, varscan2
- CACNG8 | c.332C>A p.T111K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as COSV99555004; called by muse, mutect2, varscan2
- CARF | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as COSV57547999; called by muse, mutect2, varscan2
- CASP8 | c.178T>C p.S60P | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); catalogued as COSV99965621; called by muse, mutect2, varscan2
- CCDC141 | c.4388G>T p.R1463M | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs925915791; called by muse, varscan2
- CENPC | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56626434; called by muse, mutect2, varscan2
- CEP290 | c.3715G>C p.E1239Q | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1051413485; called by muse, mutect2, varscan2
- CEP89 | c.887-1G>T p.X296_splice | Splice Site (SNP) | VAF 40/146 reads (27%) | catalogued as rs1380097876; called by muse, mutect2, varscan2
- CEP95 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56749413; called by mutect2, varscan2
- CES5A | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772022505; called by muse, mutect2, varscan2
- CFAP52 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV53307602; called by muse, mutect2, varscan2
- CFAP57 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV65264404; called by muse, mutect2, varscan2
- CLASP1 | c.3568G>C p.E1190Q | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99756622; called by muse, mutect2, varscan2
- CLCN7 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs377190713; called by muse, mutect2, varscan2
- CLEC4C | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63582218, COSV63582649; called by muse, mutect2, varscan2
- CLEC4C | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV63583253; called by muse, mutect2, varscan2
- CLVS1 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.681); catalogued as COSV57973712, COSV57984685; called by muse, mutect2, varscan2
- CNTN4 | c.2804G>C p.G935A | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61872682; called by muse, mutect2, varscan2
- CNTNAP5 | c.1381C>A p.R461S | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs752392550, COSV101443557; called by muse, mutect2, varscan2
- COL9A3 | c.1323G>A p.Q441= | Splice Region (SNP) | VAF 26/154 reads (17%) | catalogued as rs778959452; called by muse, mutect2, varscan2
- COQ7 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as rs370802219; called by muse, mutect2, varscan2
- CPXCR1 | c.229del p.Q77Kfs*9 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as COSV52161924, COSV52164465; called by mutect2, pindel, varscan2
- CSMD2 | c.4984G>C p.A1662P | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53916095; called by muse, mutect2, varscan2
- CSMD3 | c.10228A>G p.S3410G (on ENST00000297405 / NM_001363185.1; = p.S3241G on NM_052900.3) | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.214); catalogued as COSV52202283, COSV52320309; called by muse, mutect2, varscan2
- CSMD3 | c.10227C>A p.H3409Q (on ENST00000297405 / NM_001363185.1; = p.H3240Q on NM_052900.3) | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52349905; called by muse, mutect2, varscan2
- CSMD3 | c.3049G>C p.V1017L (on ENST00000297405 / NM_001363185.1; = p.V913L on NM_052900.3) | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52294403; called by muse, mutect2, varscan2
- CTSO | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as COSV70809455; called by muse, mutect2, varscan2
- CUX2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs1352666096; called by muse, mutect2, varscan2
- DCAF1 | c.2942A>G p.H981R | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.948); catalogued as rs1553631831; called by muse, mutect2, varscan2
- DCDC2C | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV52993234; called by muse, varscan2
- DCT | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as rs1201588912; called by muse, mutect2, varscan2
- DCTD | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs17849458, COSV63866858; called by muse, mutect2, varscan2
- DDX31 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs760169249; called by muse, mutect2, varscan2
- DDX3X | c.1598G>T p.R533L (on ENST00000399959; = p.R534L on NM_001356.5) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as CM158021, COSV67863295; called by muse, mutect2, varscan2
- DEFB118 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as COSV53621703, COSV99489133, COSV99489243; called by muse, mutect2, varscan2
- DENND4A | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 101/218 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs773463827, COSV71265723; called by muse, mutect2, varscan2
- DHRSX | c.202A>G p.M68V | Missense Mutation (SNP) | VAF 31/334 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as rs371831440; called by muse, mutect2
- DLL4 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV51068241; called by muse, mutect2
- DMD | c.2749C>G p.H917D | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV63741194; called by muse, mutect2, varscan2
- DMD | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs747955761; called by muse, mutect2, varscan2
- DNAH6 | c.3157G>A p.G1053S | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.187); catalogued as rs774756951; called by muse, mutect2, varscan2
- DNAH7 | c.5117T>C p.V1706A | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs988121284; called by muse, mutect2, varscan2
- DNAI4 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1426786768; called by muse, mutect2, varscan2
- DYTN | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 60/123 reads (49%) | catalogued as COSV101510804; called by muse, mutect2, varscan2
- E2F2 | c.631G>T p.G211W | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV100674760; called by muse, mutect2, varscan2
- EBF3 | c.1019C>T p.P340L (on ENST00000355311 / NM_001375392.1; = p.P331L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62475230; called by muse, mutect2, varscan2
- ECE1 | c.492C>T p.L164= | Splice Region (SNP) | VAF 94/253 reads (37%) | catalogued as rs1297396104, COSV51671630, COSV99941918; called by muse, varscan2
- EIF4A2 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1406419091; called by muse, mutect2, varscan2
- ENPEP | c.1145C>G p.S382* | Nonsense Mutation (SNP) | VAF 32/150 reads (21%) | catalogued as COSV99487073; called by muse, mutect2, varscan2
- ENPP6 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.273); catalogued as rs1169714198; called by muse, mutect2, varscan2
- EPHB1 | c.834C>A p.S278R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs748442196; called by muse, mutect2, varscan2
- EPM2A | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as CD004507; called by muse, mutect2, varscan2
- ERO1A | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV67470647; called by muse, mutect2, varscan2
- FAM111A | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1181024296; called by muse, mutect2, varscan2
- FAM135B | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52708540; called by muse, mutect2, varscan2
- FAM47A | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV60499343; called by muse, mutect2, varscan2
- FAT4 | c.10205A>G p.D3402G | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58710872; called by muse, mutect2, varscan2
- FBLN2 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs1559402643; called by muse, mutect2, varscan2
- FCGBP | c.8252C>T p.S2751L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs764233449; called by mutect2, varscan2
- FCGBP | c.4263G>T p.E1421D | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.204); catalogued as COSV55455238; called by muse, mutect2, varscan2
- FGD2 | c.1808C>A p.P603H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs760448753; called by muse, mutect2, varscan2
- FREM1 | c.4616C>A p.A1539E | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.246); catalogued as COSV101085423; called by muse, mutect2, varscan2
- GAB4 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV104434958, COSV68753776; called by muse, mutect2, varscan2
- GABRA6 | c.381C>A p.H127Q | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50880115; called by muse, mutect2, varscan2
- GABRB3 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs769693685, COSV54677415, COSV54682323; called by muse, mutect2, varscan2
- GALNT5 | c.2120G>C p.W707S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52041891; called by muse, mutect2, varscan2
- GGA3 | c.508G>C p.D170H (on ENST00000537686 / NM_138619.4; = p.D137H on NM_014001.5) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55458447; called by muse, mutect2, varscan2
- GLB1L3 | c.1344del p.S448Rfs*36 | Frame Shift Del (DEL) | VAF 47/156 reads (30%) | catalogued as COSV68392571; called by mutect2, pindel, varscan2
- GOLIM4 | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1318125131; called by muse, mutect2, varscan2
- GP6 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755790003, COSV59978363; called by muse, mutect2
- GPR158 | c.3592G>T p.A1198S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.051); catalogued as COSV66282940; called by muse, mutect2, varscan2
- GRIN2A | c.1717G>C p.V573L | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs765726510; called by muse, mutect2, varscan2
- GYS2 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 59/223 reads (26%) | catalogued as COSV53929993; called by muse, mutect2, varscan2
- H2BC4 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV58415210; called by muse, mutect2, varscan2
- HEATR1 | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV63979334; called by muse, mutect2, varscan2
- HEPH | c.916G>C p.A306P (on ENST00000343002; = p.A39P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV57963613; called by muse, mutect2, varscan2
- HEPN1 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.073); catalogued as COSV100005702; called by muse, varscan2
- HKDC1 | c.1850G>C p.G617A | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs779530620; called by muse, mutect2, varscan2
- HLCS | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV60799224; called by muse, mutect2, varscan2
- HMCN1 | c.7203G>C p.K2401N | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV54919428; called by muse, mutect2, varscan2
- HNF4A | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1290868034, CM133281, CM133282, CM133283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR2B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 74/296 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1162995939; called by muse, mutect2, varscan2
- IGHV4-28 | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1354702789; called by muse, mutect2, varscan2
- IGKV3-11 | c.130A>T p.R44W | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs781521620; called by muse, mutect2, varscan2
- INPP4A | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs781317145, COSV50798158; called by muse, mutect2, varscan2
- IPO13 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 28/198 reads (14%) | catalogued as COSV54836810; called by muse, mutect2, varscan2
- IZUMO1R | c.334C>A p.P112T (on ENST00000440961; = p.P119T on NM_001199206.3) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV60622288; called by muse, mutect2, varscan2
- KCNH7 | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV59813997; called by muse, mutect2, varscan2
- KIAA1586 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66056630; called by muse, mutect2, varscan2
- KIF18A | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs771860149; called by muse, varscan2
- KIF5A | c.2417C>T p.T806M | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs775039195, COSV54057967; called by muse, mutect2, varscan2
- KMT2D | c.10391G>T p.G3464V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV56486995; called by muse, mutect2, varscan2
- KRT36 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.23); catalogued as rs771070046; called by muse, mutect2, varscan2
- LAMA1 | c.1802A>G p.D601G | Missense Mutation (SNP) | VAF 128/272 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV67531791; called by muse, mutect2, varscan2
- LAMA1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 78/133 reads (59%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as rs377017068; called by muse, mutect2, varscan2
- LGALS9 | c.217G>C p.V73L | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100119409, COSV100119447; called by muse, mutect2, varscan2
- LILRA6 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs771563757; called by muse, mutect2, varscan2
- LPXN | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs777392551; called by muse, mutect2, varscan2
- LRP1B | c.13734T>A p.S4578R | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV101249592; called by muse, mutect2, varscan2
- LRP1B | c.7541C>T p.S2514L | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs774854037, COSV67203044, COSV67250960; called by muse, mutect2, varscan2
- LRRC55 | c.863G>C p.R288P | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV73006659, COSV73006680; called by muse, mutect2, varscan2
- LRRC8C | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100968338; called by muse, mutect2, varscan2
- LZTS3 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV61278340; called by muse, mutect2, varscan2
- MAP1S | c.2950C>T p.R984C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1447201070, COSV60722481; called by muse, mutect2
- MARVELD3 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.077); catalogued as COSV99076526; called by muse, mutect2, varscan2
- MDGA2 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.3); catalogued as rs1398673273, COSV101230778; called by muse, mutect2, varscan2
- MERTK | c.2906G>C p.W969S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV54932309; called by muse, mutect2, varscan2
- MEX3B | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs770913915, COSV61662957; called by muse, mutect2, varscan2
- MIA | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs750259359; called by muse, mutect2, varscan2
- MINDY3 | c.663_666del p.N222Sfs*3 | Frame Shift Del (DEL) | VAF 28/154 reads (18%) | catalogued as rs780473574; called by pindel, varscan2
- MKI67 | c.6022G>T p.V2008L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100896812; called by muse, mutect2, varscan2
- MKRN1 | c.773C>G p.S258W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV55439319; called by muse, mutect2
- MLXIPL | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.574); catalogued as rs868946301; called by muse, mutect2, varscan2
- MMADHC | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV57574584; called by muse, mutect2, varscan2
- MPIG6B | c.580G>C p.E194Q (on ENST00000649779 / NM_138272.3; = p.G200A on NM_025260.4) | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.167); catalogued as COSV65389405; called by muse, mutect2, varscan2
- MPO | c.961G>T p.G321W | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs761742678, COSV56565711; called by muse, mutect2, varscan2
- MROH2B | c.4666C>A p.R1556S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV68181661; called by muse, mutect2
- MROH5 | c.1242+1G>A p.X414_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as rs1363266281; called by muse, mutect2
- MUC5B | c.10366G>T p.G3456W | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs764206254, COSV71594942; called by muse, mutect2, varscan2
- MUSK | c.1215C>A p.F405L | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.289); catalogued as rs1484974390; called by muse, mutect2, varscan2
- MYH7 | c.3058C>A p.L1020M | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751904168, COSV62524364; called by muse, mutect2, varscan2
- MYOM3 | c.2616C>A p.Y872* | Nonsense Mutation (SNP) | VAF 20/120 reads (17%) | catalogued as rs768771585; called by muse, varscan2
- NBPF12 | c.2246G>T p.C749F | Missense Mutation (SNP) | VAF 124/580 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1230112813; called by muse, mutect2, varscan2
- NCAM2 | c.620-1G>T p.X207_splice | Splice Site (SNP) | VAF 29/56 reads (52%) | catalogued as COSV53063517; called by muse, mutect2, varscan2
- NEU1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV99999205; called by muse, mutect2, varscan2
- NEUROD4 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as rs926163900; called by muse, mutect2, varscan2
- NLGN1 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64343675; called by muse, mutect2, varscan2
- NLGN4X | c.1025C>A p.P342Q | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52014856; called by muse, mutect2, varscan2
- NLRC5 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52661321; called by muse, mutect2, varscan2
- NLRP8 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs778297079, COSV52584516; called by muse, mutect2, varscan2
- NPAP1 | c.1612A>T p.T538S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.583); catalogued as COSV61512031; called by muse, mutect2, varscan2
- NPAS1 | c.1269C>A p.S423R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV53409336, COSV53409974; called by muse, mutect2, varscan2
- NTSR2 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100183997; called by muse, mutect2, varscan2
- NUSAP1 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52970692; called by muse, mutect2, varscan2
- OCSTAMP | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1372363332; called by muse, mutect2, varscan2
- OR10K2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs754059809, COSV59220303; called by muse, mutect2, varscan2
- OR10Q1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs772343084, COSV57472272; called by muse, mutect2, varscan2
- OR14K1 | c.557C>G p.T186S | Missense Mutation (SNP) | VAF 137/259 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs778748863; called by muse, mutect2, varscan2
- OR2F1 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767604099; called by muse, mutect2, varscan2
- OR2T11 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100424923; called by muse, mutect2, varscan2
- OR4K15 | c.736C>A p.L246I (on ENST00000305051; = p.L222I on NM_001005486.1) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV59303902; called by muse, mutect2, varscan2
- OR4P4 | c.214A>T p.T72S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.86); catalogued as COSV58923375; called by muse, mutect2, varscan2
- OR51F1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs572940532, COSV100598680; called by muse, mutect2, varscan2
- OR51Q1 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772375558; called by muse, mutect2, varscan2
- OR56A4 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745332709; called by muse, mutect2, varscan2
- OR5AR1 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.944); catalogued as rs1393801228; called by muse, mutect2, varscan2
- OR5B2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as rs886285083; called by muse, mutect2, varscan2
- OR5D14 | c.517C>G p.P173A | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV59456870; called by muse, mutect2, varscan2
- OR5D16 | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV101003869; called by muse, mutect2
- OR5J2 | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV56623793; called by muse, mutect2, varscan2
- OTOGL | c.6893C>G p.P2298R (on ENST00000547103; = p.P2289R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086518; called by muse, mutect2, varscan2
- PAK5 | c.1379C>A p.T460N | Missense Mutation (SNP) | VAF 47/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62032154; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.265G>T p.G89C (on ENST00000259318 / NM_001136562.3; = p.G320C on NM_007203.5) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs140910746; called by muse, mutect2, varscan2
- PAPPA | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV60291334; called by muse, mutect2, varscan2
- PAX1 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as COSV68273013; called by muse, mutect2, varscan2
- PCDH8 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772666214, COSV100132076, COSV58813701; called by muse, mutect2, varscan2
- PCDH8 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.774); catalogued as rs1193490304, COSV100131288; called by muse, mutect2, varscan2
- PCDHB16 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV53360342; called by muse, mutect2, varscan2
- PCDHGB2 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV53956288; called by muse, mutect2, varscan2
- PDE1C | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.816); catalogued as rs193921048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE4DIP | c.5314G>A p.D1772N | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.079); catalogued as rs148617852; called by muse, mutect2, varscan2
- PDE5A | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53349578; called by muse, mutect2, varscan2
- PFKM | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1486845018; called by muse, mutect2, varscan2
- PKD1L1 | c.4132G>T p.V1378L | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99220936; called by muse, mutect2, varscan2
- PLCB4 | c.2558G>C p.R853T | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.154); catalogued as COSV99595600; called by muse, mutect2
- PLEKHJ1 | c.51G>C p.E17D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs1300105591, COSV55553921; called by muse, mutect2, varscan2
- PNPT1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775717775, COSV53176279; called by muse, mutect2, varscan2
- POLQ | c.7396C>T p.R2466C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372079450; called by muse, mutect2
- POM121 | c.1825A>T p.S609C (on ENST00000434423; = p.S344C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs539939964; called by mutect2, varscan2
- POU2F3 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); catalogued as rs775830481; called by muse, mutect2, varscan2
- PPP2R2B | c.700C>T p.H234Y (on ENST00000394409; = p.H300Y on NM_181674.2) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV60769931; called by muse, mutect2, varscan2
- PRKD3 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.152); catalogued as rs769950198; called by muse, mutect2, varscan2
- PROKR2 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 76/150 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM123509, COSV54089450; called by muse, mutect2, varscan2
- PRSS35 | c.1158C>A p.N386K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63801206; called by muse, mutect2, varscan2
- PSME4 | c.3164C>T p.A1055V | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs369867748, COSV66365946; called by muse, mutect2, varscan2
- PTPRD | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV61975466; called by muse, mutect2, varscan2
- PTPRT | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as rs201657236, COSV62030255; called by muse, mutect2, varscan2
- RAMP3 | c.418C>A p.R140S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.498); catalogued as COSV54245059; called by muse, varscan2
- RBFOX1 | c.924C>A p.D308E | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1196928157, COSV60964980; called by muse, mutect2, varscan2
- REG4 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV56653563; called by muse, mutect2, varscan2
- RGS5 | c.372G>C p.E124D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58353227; called by muse, mutect2, varscan2
- RIMS2 | c.2810G>T p.G937V (on ENST00000666250 / NM_001348490.2; = p.G745V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.066); catalogued as rs1231056876; called by muse, mutect2, varscan2
- ROBO1 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs377370843, COSV71398893; called by muse, mutect2, varscan2
- ROBO3 | c.2659G>A p.V887M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs1432958609; called by muse, mutect2, varscan2
- ROPN1 | c.477C>A p.S159R | Missense Mutation (SNP) | VAF 97/326 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as rs1443668318; called by muse, mutect2, varscan2
- RSPRY1 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68028547; called by muse, mutect2, varscan2
- RTCA | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV53119369; called by muse, mutect2, varscan2
- RXRG | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63233254; called by muse, mutect2, varscan2
- RYR3 | c.3645G>A p.M1215I | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs908431118, COSV66806010; called by muse, mutect2, varscan2
- SALL1 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV51762152; called by muse, mutect2, varscan2
- SARAF | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99822969; called by muse, mutect2, varscan2
- SCAF11 | c.33G>T p.M11I | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV56978185; called by muse, mutect2, varscan2
- SENP3 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1282482533; called by muse, mutect2, varscan2
- SIGMAR1 | c.76G>T p.V26F | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs556930150, COSV52844854; called by muse, mutect2, varscan2
- SKOR1 | c.1756G>T p.A586S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.964); catalogued as rs1415077497; called by muse, mutect2, varscan2
- SLC10A5 | c.1017G>T p.L339F | Missense Mutation (SNP) | VAF 28/375 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs751530257; called by muse, mutect2
- SLC25A19 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs781118725, COSV57467502; called by muse, mutect2, varscan2
- SLC2A13 | c.1424C>A p.T475K | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as rs752709836; called by muse, mutect2, varscan2
- SLC36A2 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV58865126; called by muse, mutect2, varscan2
- SLC6A13 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1028850879; called by muse, mutect2, varscan2
- SMARCA4 | c.3581G>T p.G1194V | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV60808639; called by muse, mutect2, varscan2
- SMC4 | c.3145G>C p.D1049H | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV100557482, COSV100557592; called by muse, mutect2, varscan2
- SNX7 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60268064; called by muse, mutect2, varscan2
- SOX6 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs759551935, COSV57037782; called by muse, mutect2, varscan2
- SPANXN4 | c.65G>T p.R22I | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1569428455; called by muse, mutect2, varscan2
- SPATA32 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs768384875; called by muse, mutect2, varscan2
- SRMS | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); catalogued as rs753135966; called by muse, mutect2, varscan2
- SSX1 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs782378114; called by muse, mutect2, varscan2
- STAB2 | c.4433G>T p.S1478I | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs942502138; called by muse, mutect2, varscan2
- STON2 | c.1097G>T p.W366L (on ENST00000649389 / NM_001366849.2; = p.W309L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV50843532; called by muse, mutect2, varscan2
- SYNE1 | c.18103G>C p.A6035P (on ENST00000367255 / NM_182961.4; = p.A5964P on NM_033071.3) | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV99559333; called by muse, mutect2, varscan2
- SYPL2 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV63994665; called by muse, mutect2, varscan2
- SYTL2 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100314001; called by muse, mutect2, varscan2
- TAF3 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60203282; called by muse, mutect2, varscan2
- TANGO2 | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs371101680; called by muse, mutect2, varscan2
- TAS2R16 | c.783G>C p.W261C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV99972328; called by muse, mutect2, varscan2
- TBXA2R | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.165); catalogued as COSV100916247; called by muse, mutect2, varscan2
- TCF4 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV61892317; called by muse, mutect2, varscan2
- TEP1 | c.6643G>T p.G2215W | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766727831, COSV52989620; called by muse, mutect2, varscan2
- TEX15 | c.8290C>A p.L2764I (on ENST00000256246; = p.L3147I on NM_001350162.2) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV56346300; called by muse, mutect2, varscan2
- TF | c.1387del p.L463* | Frame Shift Del (DEL) | VAF 79/253 reads (31%) | catalogued as COSV53920624; called by mutect2, pindel, varscan2
- THSD1 | c.1398G>C p.E466D | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV51626517, COSV99318974; called by muse, mutect2, varscan2
- THSD7A | c.880C>G p.P294A | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV70263234, COSV70273036; called by muse, mutect2, varscan2
- THSD7A | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV101448831, COSV70264736; called by muse, mutect2, varscan2
- TMC4 | c.374C>T p.A125V (on ENST00000617472 / NM_001145303.3; = p.A119V on NM_144686.4) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as rs976440874; called by muse, mutect2, varscan2
- TMEM132D | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV101399105, COSV70600264; called by muse, mutect2, varscan2
- TMEM151A | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV59173864; called by muse, mutect2, varscan2
- TMEM168 | c.211G>C p.G71R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57181370; called by muse, mutect2, varscan2
- TMPRSS7 | c.343C>T p.R115C (on ENST00000452346; = p.R3C on NM_001042575.2) | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs752819704, COSV69979789; called by muse, mutect2, varscan2
- TNIP1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.95); catalogued as rs201360054, COSV59306429; called by muse, mutect2, varscan2
- TOGARAM1 | c.4519A>G p.I1507V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV63890687; called by muse, mutect2, varscan2
- TP53 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as COSV52783832, COSV52937658, COSV53407681; called by muse, mutect2, varscan2
- TPSD1 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1322028995; called by muse, mutect2
- TRPM2 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV55968653; called by muse, varscan2
- TRPV1 | c.2269G>C p.V757L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51520891; called by muse, mutect2, varscan2
- TTC39A | c.123C>T p.P41= | Splice Region (SNP) | VAF 9/71 reads (13%) | catalogued as rs576897859; called by muse, mutect2
- TTC7B | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs145204823; called by muse, mutect2, varscan2
- TTN | c.77482C>A p.P25828T (on ENST00000591111; = p.P18404T on NM_003319.4) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | PolyPhen benign (0.003); catalogued as rs769678793; called by muse, mutect2, varscan2
- TTN | c.61831C>A p.P20611T (on ENST00000591111; = p.P13187T on NM_003319.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | PolyPhen benign (0.306); catalogued as COSV60020986; called by muse, mutect2, varscan2
- TTN | c.40160-1G>A p.X13387_splice (on ENST00000591111; = p.X5963_splice on NM_003319.4) | Splice Site (SNP) | VAF 37/199 reads (19%) | catalogued as rs1478618005; called by muse, mutect2, varscan2
- TTN | c.8902C>A p.P2968T (on ENST00000591111; = p.P2922T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | PolyPhen probably damaging (0.999); catalogued as rs773875566, COSV100631490, COSV60107027; called by muse, mutect2, varscan2
- TTN | c.7469G>T p.R2490L (on ENST00000591111; = p.R2444L on NM_003319.4) | Missense Mutation (SNP) | VAF 72/423 reads (17%) | PolyPhen possibly damaging (0.834); catalogued as rs148920986, COSV100629405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE3B | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 103/146 reads (71%) | catalogued as COSV55094119; called by muse, varscan2
- UGT1A9 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs768335644; called by muse, mutect2, varscan2
- UGT1A9 | c.455A>C p.N152T | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs746650868; called by muse, mutect2, varscan2
- UNC80 | c.2389G>A p.V797M | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs796216121; called by muse, mutect2, varscan2
- UPF2 | c.3807del p.R1270Gfs*45 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as COSV62659393; called by mutect2, pindel, varscan2
- UPP2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs764369730, COSV50046245, COSV50046996; called by muse, mutect2, varscan2
- UTY | c.1964C>G p.S655* | Nonsense Mutation (SNP) | VAF 105/162 reads (65%) | catalogued as COSV100229582; called by muse, mutect2, varscan2
- VAPB | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55667382; called by muse, mutect2, varscan2
- VCPKMT | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99366682; called by muse, mutect2, varscan2
- VIM | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV56407448; called by muse, mutect2, varscan2
- WNK4 | c.887C>G p.P296R | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53821678; called by muse, mutect2, varscan2
- WRN | c.355+1G>T p.X119_splice | Splice Site (SNP) | VAF 128/285 reads (45%) | catalogued as rs775196937, COSV53309037; called by muse, mutect2, varscan2
- WT1 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); catalogued as rs554416372, CM116565, CM159874, COSV60065661, COSV60065744, COSV60067902, COSV60068332, COSV60071203, COSV60072077; called by muse, mutect2, varscan2
- XIRP2 | c.302T>A p.L101Q | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as rs1252078848; called by muse, mutect2, varscan2
- ZBBX | c.1584C>A p.S528R | Missense Mutation (SNP) | VAF 97/198 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs775962585; called by muse, mutect2, varscan2
- ZNF208 | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763924394, COSV68112629; called by muse, varscan2
- ZNF366 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs374146709, COSV59216598; called by muse, mutect2, varscan2
- ZNF492 | c.1293C>A p.N431K | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as rs1411516310; called by mutect2, varscan2
- ZNF536 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100835035; called by muse, mutect2, varscan2
- ZNF665 | c.1402C>G p.Q468E (on ENST00000600412; = p.Q533E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV101128370; called by muse, mutect2, varscan2
- ZNF716 | c.165G>T p.L55= | Splice Region (SNP) | VAF 16/141 reads (11%) | catalogued as COSV70781838; called by muse, mutect2, varscan2
- ZNF717 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV68858615; called by muse, mutect2, varscan2
- ZNF737 | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs781949903; called by muse, mutect2, varscan2
- ZNF804A | c.1298G>T p.R433I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs779623841, COSV56448346; called by muse, mutect2, varscan2
- ZNF804A | c.2286G>A p.M762I | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1261022757; called by muse, mutect2, varscan2
- ZNF831 | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as COSV64040765; called by muse, mutect2, varscan2
- ZNF98 | c.1416C>A p.N472K | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.05); catalogued as rs781756954; called by muse, mutect2, varscan2
- ZSWIM1 | c.576G>C p.R192S | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1410679273; called by muse, mutect2, varscan2
- AARS1 | c.1717G>A p.V573M | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AASS | c.1574_1576del p.N525del | In Frame Del (DEL) | VAF 76/241 reads (32%) | called by pindel, varscan2
- ABCE1 | c.554dup p.S186Ifs*8 | Frame Shift Ins (INS) | VAF 87/277 reads (31%) | called by mutect2, pindel, varscan2
- ACADM | c.369dup p.E124* | Frame Shift Ins (INS) | VAF 44/176 reads (25%) | called by mutect2, pindel, varscan2
- ACSBG1 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ACSM2B | c.526T>A p.S176T | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACVR1 | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADA | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 93/537 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS12 | c.1756A>T p.K586* | Nonsense Mutation (SNP) | VAF 76/158 reads (48%) | called by muse, varscan2
- ADAMTS12 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADAMTS20 | c.4621C>A p.L1541M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADAMTS4 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4357G>A p.V1453M | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ADGRA3 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF5 | c.1808A>G p.H603R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL3 | c.3638G>T p.G1213V (on ENST00000506720 / NM_001322402.2; = p.G1145V on NM_015236.6) | Missense Mutation (SNP) | VAF 109/204 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ADPRM | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ADPRS | c.213A>G p.E71= | Splice Region (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- ADRA2C | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.11513C>A p.P3838H | Missense Mutation (SNP) | VAF 130/458 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- AHNAK2 | c.5696G>T p.G1899V | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- AIRE | c.840dup p.A281Rfs*8 | Frame Shift Ins (INS) | VAF 19/85 reads (22%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.2204T>G p.I735S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ALB | c.1325T>G p.V442G | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ALCAM | c.648G>C p.M216I | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDH8A1 | c.1012-2A>T p.X338_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- ALG1 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER3 | c.1167T>A p.D389E | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- AMER3 | c.2020G>C p.A674P | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ANAPC1 | c.2812G>T p.G938* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- ANAPC1 | c.1185T>A p.F395L | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2
- ANGPT1 | c.945C>A p.C315* | Nonsense Mutation (SNP) | VAF 44/222 reads (20%) | called by muse, mutect2, varscan2
- ANGPTL8 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ANKLE1 | c.1784A>G p.H595R (on ENST00000394458; = p.H541R on NM_152363.6) | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ANKS1B | c.1660A>T p.T554S | Missense Mutation (SNP) | VAF 67/579 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANTXRL | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ANTXRL | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANXA2R | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- AOAH | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- AOX1 | c.2992G>A p.A998T | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- APOBEC4 | c.602T>C p.F201S | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- APP | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ARHGAP12 | c.685-1G>T p.X229_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.418T>A p.C140S | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ARHGAP26 | c.1229T>A p.L410Q | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP32 | c.1277A>G p.H426R (on ENST00000310343 / NM_001378025.1; = p.H77R on NM_014715.4) | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARHGAP44 | c.2227C>A p.P743T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ARHGAP9 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARL6IP1 | c.36+1G>T p.X12_splice | Splice Site (SNP) | VAF 27/141 reads (19%) | called by muse, mutect2, varscan2
- ARL8B | c.482C>G p.S161* | Nonsense Mutation (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- ARMC3 | c.1252G>C p.A418P | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMCX2 | c.1676A>G p.N559S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ARMCX5 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMH4 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ARNTL2 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- AS3MT | c.158A>C p.E53A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ASIC4 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASTN1 | c.1388G>A p.C463Y | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATG4D | c.1349_1360del p.P450_R453del | In Frame Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.3118G>C p.V1040L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATR | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRN | c.2051A>C p.E684A | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRNL1 | c.1687G>T p.A563S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- AXL | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AZU1 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 138/400 reads (35%) | called by pindel, varscan2
- B4GALNT3 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- BAP1 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 50/98 reads (51%) | called by muse, varscan2
- BBX | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BDP1 | c.1148A>C p.Q383P | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BICD1 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- BIN2 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BIRC6 | c.9179A>T p.Y3060F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- BMP1 | c.1821G>A p.W607* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- BOLL | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- BRCA2 | c.4391C>A p.S1464Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- BSX | c.586A>T p.T196S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD1 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- BTBD7 | c.428A>C p.D143A | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1orf87 | c.11C>A p.A4D | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- C6 | c.1675T>A p.Y559N | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- C6 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- C6orf132 | c.2747G>T p.W916L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C8A | c.898C>A p.H300N | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- C8orf34 | c.496dup p.D166Gfs*6 | Frame Shift Ins (INS) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- CAB39L | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CACNA1A | c.4308C>A p.D1436E | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CACNA1C | c.2409G>C p.K803N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CACNG5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CADM2 | c.71G>T p.G24V (on ENST00000407528 / NM_001167674.2; = p.G26V on NM_153184.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CALCA | c.176T>G p.V59G | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CALHM1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, varscan2
- CAMKMT | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CAPN11 | c.1619C>A p.T540N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CAPN8 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CATSPER1 | c.1704C>G p.S568R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CCDC150 | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CCDC183 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC74A | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- CCDC82 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- CD300LB | c.147G>T p.W49C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC25B | c.943T>C p.C315R (on ENST00000245960 / NM_021873.3; = p.C301R on NM_004358.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2
- CDCA2 | c.2143G>T p.A715S | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CDH23 | c.1829T>C p.F610S | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CEP128 | c.1209+3G>T | Splice Region (SNP) | VAF 73/282 reads (26%) | called by muse, mutect2, varscan2
- CEP350 | c.3131A>C p.H1044P | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP44 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CFAP46 | c.7155del p.K2387Rfs*4 | Frame Shift Del (DEL) | VAF 59/117 reads (50%) | called by mutect2, pindel, varscan2
- CFAP47 | c.8119G>C p.V2707L | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CFAP54 | c.5468G>C p.C1823S | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CFAP58 | c.98A>T p.D33V | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAD | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD7 | c.5812G>C p.D1938H | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CHML | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CINP | c.472A>T p.K158* | Nonsense Mutation (SNP) | VAF 31/192 reads (16%) | called by muse, mutect2, varscan2
- CIPC | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CLEC14A | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by mutect2, varscan2
- CLEC18B | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 42/726 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CLEC4E | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLMP | c.776A>C p.K259T | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CLSTN1 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLU | c.584T>A p.F195Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CNGA2 | c.1936G>T p.D646Y | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by mutect2, varscan2
- CNGB3 | c.837A>T p.R279S | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CNNM1 | c.2005G>T p.D669Y | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CNP | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- CNTN6 | c.2339T>C p.V780A | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CNTNAP2 | c.2371T>G p.C791G | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTNAP5 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- COA3 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- COL11A1 | c.1662G>T p.E554D | Missense Mutation (SNP) | VAF 133/400 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL19A1 | c.1112C>G p.P371R | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- COL1A2 | c.3580T>C p.Y1194H | Missense Mutation (SNP) | VAF 43/361 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- COL6A2 | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COLEC10 | c.221-1G>A p.X74_splice | Splice Site (SNP) | VAF 57/167 reads (34%) | called by muse, mutect2, varscan2
- COMP | c.1136-1G>A p.X379_splice | Splice Site (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- COQ8B | c.1553G>T p.R518L | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CPSF6 | c.772G>C p.V258L | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CPVL | c.1160T>A p.L387Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACDL | c.623A>T p.D208V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CREBRF | c.467A>T p.Y156F | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- CRISP3 | c.166G>A p.D56N (on ENST00000371159 / NM_001368123.1; = p.D38N on NM_006061.4) | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CSE1L | c.2431G>C p.D811H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.5822A>T p.Q1941L (on ENST00000520002; = p.Q1940L on NM_033225.6) | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CSMD3 | c.3710G>T p.C1237F (on ENST00000297405 / NM_001363185.1; = p.C1133F on NM_052900.3) | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSRNP1 | c.204C>A p.T68= | Splice Region (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- CTAGE9 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 271/657 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CTSK | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CX3CL1 | c.512del p.P171Rfs*258 | Frame Shift Del (DEL) | VAF 33/62 reads (53%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CYP1B1 | c.1377A>T p.R459S | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP7A1 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DCBLD2 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCDC1 | c.2866G>C p.G956R (on ENST00000597505 / NM_001367979.1; = p.G63R on NM_020869.3) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- DEAF1 | c.573A>C p.K191N | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DENND2A | c.1290G>T p.R430S | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- DENND2C | c.1059C>G p.L353= | Splice Region (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- DERPC | c.889G>C p.G297R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DISC1 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DLG5 | c.5039T>A p.L1680Q | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DLL4 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.073); called by muse, mutect2
- DMD | c.3351T>A p.N1117K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMD | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 139/231 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DMXL1 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DNAH10 | c.3730A>C p.T1244P (on ENST00000409039; = p.T1183P on NM_207437.3) | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH5 | c.7948A>T p.K2650* | Nonsense Mutation (SNP) | VAF 42/283 reads (15%) | called by muse, mutect2, varscan2
- DNAH6 | c.11018C>G p.P3673R | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DNAH8 | c.5273T>C p.I1758T | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAH9 | c.4970A>T p.Y1657F | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DNAJC6 | c.1345G>T p.V449L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.956); called by muse, mutect2
- DNMT3L | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK10 | c.3075T>A p.N1025K | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DOCK4 | c.1449del p.H484Tfs*27 | Frame Shift Del (DEL) | VAF 38/108 reads (35%) | called by mutect2, pindel, varscan2
- DPYD | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSEL | c.3190G>T p.V1064L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DST | c.21425G>T p.G7142V (on ENST00000361203 / NM_001374722.1; = p.G4839V on NM_015548.5) | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.19411G>T p.E6471* (on ENST00000361203 / NM_001374722.1; = p.E4168* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | called by muse, varscan2
- DYNC1I1 | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1LI2 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- DZANK1 | c.1991G>A p.G664E (on ENST00000262547 / NM_001099407.1; = p.G471E on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ECEL1 | c.642_643delinsA p.G215Afs*128 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | called by pindel, varscan2*
- EEA1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 40/255 reads (16%) | called by muse, mutect2, varscan2
- EIF3E | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- EIF4E1B | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ENPP2 | c.499A>C p.I167L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPG5 | c.6029C>G p.S2010* | Nonsense Mutation (SNP) | VAF 32/206 reads (16%) | called by muse, mutect2, varscan2
- EPN1 | c.710G>T p.R237L (on ENST00000270460 / NM_001321263.1; = p.R212L on NM_013333.3) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EPS15 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- ERBB4 | c.3545C>A p.A1182E | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ERC1 | c.1654A>G p.K552E (on ENST00000360905 / NM_178040.4; = p.K524E on NM_178039.4) | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ERLIN2 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 66/388 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ERV3-1 | c.1257G>T p.W419C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, varscan2
- ESCO1 | c.54A>T p.K18N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- ESYT1 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ESYT3 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ETFDH | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETV1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EVX2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- EXOSC7 | c.616-2A>G p.X206_splice | Splice Site (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- EXPH5 | c.4634A>T p.Q1545L | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- FAM171A1 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- FAM184A | c.599A>G p.E200G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM189A1 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- FAM234A | c.956G>T p.R319M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- FAM83G | c.2336A>G p.H779R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM90A10P | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- FAT1 | c.10168G>T p.G3390* | Nonsense Mutation (SNP) | VAF 25/147 reads (17%) | called by muse, mutect2, varscan2
- FAT3 | c.8605G>T p.D2869Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCAMR | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- FGA | c.1964C>A p.S655Y | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- FGG | c.369del p.A124Hfs*4 | Frame Shift Del (DEL) | VAF 43/187 reads (23%) | called by mutect2, pindel, varscan2
- FLNA | c.2387G>A p.C796Y | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FN1 | c.1545A>T p.R515= | Splice Region (SNP) | VAF 101/299 reads (34%) | called by muse, mutect2, varscan2
- FOLH1 | c.1757A>T p.E586V | Missense Mutation (SNP) | VAF 48/389 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FRAS1 | c.10937C>T p.P3646L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- FREM1 | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.345); called by muse, mutect2
- FREM2 | c.2170A>T p.K724* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- FREM3 | c.1604_1606del p.T535del | In Frame Del (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.2960C>A p.P987Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- FTCD | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FTO | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 181/467 reads (39%) | called by muse, mutect2, varscan2
- GABRG3 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 39/203 reads (19%) | called by muse, mutect2, varscan2
- GADD45A | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); called by muse, mutect2
- GALC | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 133/536 reads (25%) | called by muse, mutect2, varscan2
- GFI1B | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- GFM1 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 174/278 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GIGYF1 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- GIMAP8 | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2
- GIT2 | c.269G>T p.R90I | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GOLGB1 | c.8754G>T p.K2918N | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- GPC6 | c.1146C>A p.D382E | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- GPR42 | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 88/263 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by mutect2, varscan2
- GPR55 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR6 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GPR85 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- GPR87 | c.758G>T p.S253I | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPRIN3 | c.808del p.L270Sfs*32 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- GPS2 | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.141); called by muse, mutect2
- GRB10 | c.571A>T p.R191* | Nonsense Mutation (SNP) | VAF 144/378 reads (38%) | called by muse, mutect2, varscan2
- GRM3 | c.2612T>A p.V871D | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- GSDMA | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSK3B | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H3C1 | c.120C>G p.H40Q | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- H4C3 | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- HACE1 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- HAUS5 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- HAUS7 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HDAC11 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- HDAC9 | c.2958C>A p.H986Q | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR1 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HEPH | c.3321G>C p.M1107I (on ENST00000343002; = p.M840I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPHL1 | c.1697T>C p.L566P | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HERC6 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HMBS | c.34-4G>A | Splice Region (SNP) | VAF 69/407 reads (17%) | called by muse, mutect2, varscan2
- HMGXB3 | c.3846G>T p.L1282F (on ENST00000613459; = p.L1036F on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HOOK1 | c.1088A>G p.K363R | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HRH2 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HS3ST5 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- HSD17B12 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSP90AA1 | c.1562T>G p.M521R | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HTR1A | c.1212C>A p.N404K | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HUWE1 | c.1067A>G p.H356R | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYOU1 | c.2554G>T p.V852L | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ICAM3 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICE2 | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 105/257 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- IFNA16 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 106/215 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IFNLR1 | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IGHD1-7 | c.2G>T p.G1V | Missense Mutation (SNP) | VAF 22/243 reads (9%) | PolyPhen possibly damaging (0.528); called by muse, mutect2
- IGHM | c.1344G>T p.W448C | Missense Mutation (SNP) | VAF 35/415 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2
- IGHM | c.1028T>A p.L343Q | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- IGHM | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- IGHV3-13 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- IGKV3-7 | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGSF21 | c.578T>G p.V193G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.587); called by mutect2, varscan2
- IL20RA | c.546C>A p.N182K | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- IL2RA | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- INTS6 | c.2151T>G p.N717K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.045); called by mutect2, varscan2
- INTS6 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- IRF8 | c.975C>A p.S325R | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IRGC | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRS2 | c.2408A>G p.Y803C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ITIH5 | c.1734C>A p.S578R | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ITPR2 | c.2445-2A>G p.X815_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2
- JAG1 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, varscan2
- JAKMIP1 | c.728T>C p.L243S | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- JPH4 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- KAZALD1 | c.513G>T p.G171= | Splice Region (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2
- KCNC2 | c.1373C>A p.A458D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK10 | c.1479G>T p.M493I | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK10 | c.853G>C p.G285R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- KCNN3 | c.688C>A p.H230N | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNT2 | c.478A>T p.R160W | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KCTD3 | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCTD7 | c.560C>T p.P187L (on ENST00000275532; = p.T200= on NM_153033.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.856); called by muse, mutect2
- KHDC4 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- KIAA0895L | c.1085del p.Q362Rfs*51 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.1582C>A p.H528N | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIAA1671 | c.3267G>T p.M1089I | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF19 | c.2612G>C p.G871A | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIR3DL2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIR3DL3 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- KIR3DL3 | c.663T>A p.Y221* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- KLF12 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL4 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- KLHL41 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- KMT2A | c.5037T>G p.S1679R | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- KNTC1 | c.2414A>T p.Y805F | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- LAMA2 | c.1603G>T p.G535C | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LARGE2 | c.1349G>T p.C450F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- LARP1B | c.2515A>T p.S839C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- LDHC | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LEKR1 | c.311A>G p.Q104R | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- LEKR1 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 43/412 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LEPR | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 71/351 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- LEPR | c.3233A>G p.Y1078C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHX5 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- LILRA5 | c.802C>A p.R268S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- LINC01205 | n.227+5G>T | Splice Region (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- LLGL1 | c.1189T>C p.C397R | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- LNPEP | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRBA | c.6463A>G p.I2155V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LRIT1 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRP12 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.4286G>A p.G1429E | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP6 | c.449G>C p.G150A | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2
- LRRC66 | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 146/372 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRRK2 | c.5787C>A p.H1929Q | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRTM1 | c.1057G>T p.V353F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- LY9 | c.1033A>T p.S345C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- LYAR | c.627A>T p.E209D | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- M1AP | c.1125C>G p.H375Q | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- MACF1 | c.7473_7474del p.G2492Sfs*13 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | called by pindel, varscan2
- MACROD2 | c.1130A>C p.Y377S (on ENST00000642719; = p.Y349S on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEB2 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MAGEE1 | c.2104G>T p.G702C | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MAGT1 | c.193G>T p.V65L (on ENST00000618282 / NM_001367916.1; = p.V97L on NM_032121.5) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MAK | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- MALRD1 | c.2362T>A p.F788I | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALRD1 | c.2842C>A p.H948N | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MAMLD1 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAP4K3 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAST1 | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- MAST3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MBIP | c.889-6dup | Splice Region (INS) | VAF 12/88 reads (14%) | called by pindel, varscan2
- MCM2 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCOLN2 | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED1 | c.1978C>G p.L660V | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MED1 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- MED6 | c.247A>T p.K83* | Nonsense Mutation (SNP) | VAF 48/202 reads (24%) | called by muse, mutect2, varscan2
- MERTK | c.1175T>A p.V392E | Missense Mutation (SNP) | VAF 67/375 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MGAT4B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MGMT | c.548G>T p.S183I (on ENST00000306010; = p.S152I on NM_002412.5) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MICAL2 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MICALL1 | c.2339G>T p.R780L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MIER1 | c.1153A>T p.S385C (on ENST00000355356 / NM_001077701.3; = p.S402C on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MINPP1 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MKRN3 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP16 | c.1730del p.L577Pfs*47 | Frame Shift Del (DEL) | VAF 42/270 reads (16%) | called by mutect2, pindel, varscan2
- MOB1B | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRC1 | c.1881C>A p.H627Q | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- MRGPRG | c.287T>A p.L96Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- MRPL38 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRTFA | c.1598T>C p.V533A | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MRTFB | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MS4A1 | c.681A>G p.I227M | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MS4A14 | c.1636C>G p.H546D | Missense Mutation (SNP) | VAF 117/339 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- MSANTD2 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- MTMR9 | c.1203G>T p.L401F | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MTRR | c.1339G>A p.A447T (on ENST00000264668; = p.A420T on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MTX2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MUC12 | c.5435C>A p.S1812* (on ENST00000379442; = p.S1669* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 61/273 reads (22%) | called by muse, mutect2, varscan2
- MUC12 | c.14929T>A p.S4977T (on ENST00000379442; = p.S4834T on NM_001164462.1) | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT tolerated (0.86); called by muse, mutect2, varscan2
- MUL1 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYH4 | c.2957T>C p.M986T | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MYO7B | c.3878G>T p.W1293L | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MYT1 | c.2591+1G>T p.X864_splice | Splice Site (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- NAALADL1 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAP1L4 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- NAV3 | c.3330A>T p.R1110S | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCAM1 | c.1674G>C p.K558N (on ENST00000316851 / NM_181351.5; = p.K548N on NM_000615.7) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- NDUFB10 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NDUFS8 | c.457T>A p.C153S | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NECTIN3 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 68/474 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEIL3 | c.1434A>C p.K478N | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFIA | c.817A>T p.S273C | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- NKAP | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NKX1-1 | c.227C>G p.P76R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- NLRC3 | c.1810C>A p.L604M | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRC5 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NOMO2 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2
- NOS1AP | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NOTCH3 | c.4861G>A p.D1621N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NPAP1 | c.562A>T p.T188S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NPFFR2 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.026); called by muse, varscan2
- NRG3 | c.2016A>T p.E672D (on ENST00000404547 / NM_001370084.1; = p.E648D on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NRK | c.4297T>C p.Y1433H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NRXN1 | c.2245C>A p.Q749K | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); called by mutect2, varscan2
- NSMCE3 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- NUMA1 | c.3976G>T p.G1326C | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OBSCN | c.20014C>A p.L6672I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OBSL1 | c.3650A>T p.E1217V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ODF3L2 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OLIG3 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- OR10H3 | c.684G>C p.L228F | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR2A25 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- OR2G2 | c.279A>T p.K93N | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2G6 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4A15 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.179); called by muse, mutect2
- OR4C11 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4D5 | c.827C>A p.T276K | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- OR4K5 | c.925del p.R309Gfs*8 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- OR4Q3 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR51B4 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- OR51L1 | c.438dup p.G147Wfs*79 | Frame Shift Ins (INS) | VAF 40/240 reads (17%) | called by mutect2, pindel, varscan2
- OR52B4 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR52N1 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR56A5 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- OR5F1 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- OR5K1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR6Y1 | c.737G>C p.C246S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOGL | c.159A>T p.L53F (on ENST00000547103; = p.L44F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- OTP | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- OVCH1 | c.3013A>C p.M1005L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OXCT1 | c.994T>A p.F332I | Missense Mutation (SNP) | VAF 73/425 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- P2RX3 | c.77T>A p.I26N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PALLD | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PAPLN | c.1819G>T p.G607C (on ENST00000554301; = p.G580C on NM_173462.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- PAPPA2 | c.5094C>A p.D1698E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PASK | c.2377G>T p.D793Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- PBX1 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- PCDHB12 | c.1271C>A p.T424N | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PCDHGB4 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCK1 | c.1605G>T p.R535S | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCOLCE | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCYT1B | c.934C>A p.Q312K | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDCL | c.332T>A p.L111H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PDP2 | c.1340A>T p.N447I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- PEG3 | c.2944T>A p.S982T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- PEX11B | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PEX2 | c.342G>T p.R114S | Missense Mutation (SNP) | VAF 62/494 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PFKL | c.1899C>G p.Y633* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- PHLPP2 | c.2811C>G p.I937M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIGF | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
717 further variants in this file (246 protein-altering or splice-affecting, 298 silent, 173 other) are not listed here.
